Gene-level copy-number profile of tumor specimen TCGA-BB-A5HY-01A from TCGA case TCGA-BB-A5HY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.7 years (23,640 days).
Specimen TCGA-BB-A5HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.26b97c11-4d1e-4bfb-a2c5-48698b59107b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-A5HY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aeb31e5d-2538-4f7b-8bd6-e90070ff9739

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 208; copy number 1: 29,656; copy number 2: 20,181; copy number 3: 6,193; copy number 4: 1,485; copy number 5: 1,585; copy number 6: 258; copy number 8: 113; copy number 9: 75; copy number 10: 19; copy number 11: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-A5HY-01A-11D-A28Q-01): tumor purity 0.6, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 208 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,488,300–11,529,755, 2 genes: AC026185.1, AC022001.1.
- chr5:59,314,110–59,703,703, 3 genes: AC008833.1, NDUFB4P2, MIR582.
- chr6:156,776,020–157,210,779, 1 gene (within-gene range 0–2): ARID1B.
- chr6:156,976,294–157,119,706, 2 genes: AL162578.1, AL049820.1.
- chr8:2,935,353–4,994,972, 1 gene (within-gene range 0–1): CSMD1.
- chr8:3,700,492–4,788,584, 5 genes: RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr12:24,212,421–24,260,056, 2 genes: MIR920, SOX5-AS1.
- chr13:18,467,172–25,210,295, 189 genes (broad region; genes not listed).
- chr14:66,507,407–67,181,803, 1 gene (within-gene range 0–2): GPHN.
- chr14:66,969,038–66,969,816, 1 gene: AL049835.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 9,732 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,555,040–240,776,824, 48 genes, copy number 3: AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,823,433, 1 gene, copy number 3: RFKP1.
- chr2:163,743,913–165,208,261, 12 genes, copy number 3 (within-gene range 1–3): AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11.
- chr2:177,623,244–184,939,492, 93 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:11,745–10,127,190, 129 genes, copy number 4–5 (within-gene range 1–5) (broad region; genes not listed).
- chr3:135,925,891–198,222,513, 1,087 genes, copy number 5–6 (broad region; genes not listed).
- chr4:48,986,275–52,723,623, 36 genes, copy number 3: CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR.
- chr4:52,712,682–52,751,586, 6 genes, copy number 3: MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1.
- chr4:53,265,461–56,821,742, 82 genes, copy number 3 (broad region; genes not listed).
- chr5:36,035,021–37,066,413, 20 genes, copy number 4 (within-gene range 1–4): UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31.
- chr5:38,682,070–45,696,498, 109 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr5:50,396,192–52,080,987, 25 genes, copy number 8: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr5:122,114,598–122,311,673, 5 genes, copy number 3 (within-gene range 1–3): AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2.
- chr5:144,856,890–181,342,213, 701 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr6:30,414,715–57,222,307, 776 genes, copy number 3 (broad region; genes not listed).
- chr6:67,878,316–68,329,899, 8 genes, copy number 3: AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549.
- chr6:122,975,198–127,213,609, 32 genes, copy number 3 (within-gene range 2–3): AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1.
- chr6:131,780,721–133,150,816, 46 genes, copy number 3: AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4.
- chr7:26,667,068–49,587,165, 442 genes, copy number 3 (broad region; genes not listed).
- chr7:54,330,670–69,174,450, 367 genes, copy number 3–11 (broad region; genes not listed).
- chr7:93,099,513–96,709,891, 60 genes, copy number 3–4: SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1.
- chr8:35,235,475–35,796,550, 4 genes, copy number 4 (within-gene range 1–4): UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:46,028,804–145,066,685, 1,533 genes, copy number 3–5 (broad region; genes not listed).
- chr9:136,935,840–138,203,325, 75 genes, copy number 4 (broad region; genes not listed).
- chr11:167,784–2,849,105, 149 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:6,297,189–42,253,721, 580 genes, copy number 3 (broad region; genes not listed).
- chr11:49,081,907–49,208,638, 7 genes, copy number 5: UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1.
- chr11:54,591,480–59,520,703, 252 genes, copy number 3–4 (broad region; genes not listed).
- chr12:44,498,616–81,998,962, 1,000 genes, copy number 3–5 (broad region; genes not listed).
- chr14:24,809,656–25,050,297, 1 gene, copy number 3 (within-gene range 2–3): STXBP6.
- chr14:25,124,467–27,295,516, 18 genes, copy number 3 (within-gene range 2–3): LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr17:33,013,087–34,174,964, 1 gene, copy number 4 (within-gene range 1–4): ASIC2.
- chr17:33,565,764–34,165,736, 16 genes, copy number 4 (within-gene range 2–4): AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2.
- chr18:47,390–3,025,566, 70 genes, copy number 3 (broad region; genes not listed).
- chr18:3,093,568–3,093,629, 1 gene, copy number 3: RNU7-25P.
- chr19:54,351,384–58,605,223, 310 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 3 (broad region; genes not listed).
- chr22:38,200,767–38,575,431, 17 genes, copy number 5: MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.2, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31.
- chr22:38,952,741–42,858,106, 151 genes, copy number 5–9 (broad region; genes not listed).
- chr22:42,853,403–42,853,799, 1 gene, copy number 5: AL049758.1.

Autosomal genes at a single copy (total copy number 1): 29,065. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
